MMRF case MMRF_2399 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1633986b-fede-4031-90de-f15287d591ae

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.3 years (19,474 days); ISS stage: I; Days to last known disease status: 736 days (2.0 years); Days to last follow up: 736 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 121 mg/dL; Immunoglobulin G 3.37 g/L; Immunoglobulin A 35.6 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 8.6 g/dL; Glucose 6.05 mmol/L; C-Reactive Protein 0.135 mg/dL.
- Day 92 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.4 mg/dL; Immunoglobulin G 2.95 g/L; Immunoglobulin A 11.8 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 9.02 mmol/L.
- Day 184 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.3 mg/dL; Immunoglobulin G 2.38 g/L; Immunoglobulin A 7.32 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 14.6 ×10⁹/L; Absolute Neutrophil 13.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 7.04 mmol/L.
- Day 268 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.79 mg/dL; Immunoglobulin G 2.4 g/L; Immunoglobulin A 2.51 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 8.36 mmol/L.
- Day 352 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.75 mg/dL; Immunoglobulin G 1.94 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 7.45 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 5.56 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.7 mg/dL; Immunoglobulin G 4.28 g/L; Immunoglobulin A 2.74 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.55 mmol/L.
- Day 547: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.52 mg/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 3.72 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 3.03 mmol/L.
- Day 631 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.1 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 4.32 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 736 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.8 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 3.51 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -7: Weight: 85 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2399_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2399_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
